TCGA case TCGA-20-0996 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Fox Chase Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d7f82e34-5b34-4e8c-a0cf-d7561bcea43c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 59.1 years (21,572 days); Year of diagnosis: 2001; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No; Days to last follow up: 2,196 days (6.0 years).
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 168 days; Days to treatment end: 224 days; Number of cycles: 3; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 168 days; Days to treatment end: 224 days; Number of cycles: 3; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Treatment intent type: Adjuvant; Days to treatment start: 443 days (1.2 years); Days to treatment end: 590 days (1.6 years); Number of cycles: 15; Treatment dose: 4 mg/m2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 616 days (1.7 years); Days to treatment end: 1,078 days (3.0 years); Number of cycles: 13; Treatment dose: 40 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 1,106 days (3.0 years); Number of cycles: 6; Treatment dose: 50 mg; Route of administration: Oral.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 2,196 days (6.0 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-20-0996-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.8; Shortest dimension: 0.8.
  Slide TCGA-20-0996-01A-01-BS1: Section location: Top; Percent tumor cells: 64; Percent tumor nuclei: 75; Percent normal cells: 35; Percent necrosis: 1; Percent stromal cells: 0.
  Slide TCGA-20-0996-01A-02-BS2: Section location: Bottom; Percent tumor cells: 69; Percent tumor nuclei: 80; Percent normal cells: 30; Percent necrosis: 1; Percent stromal cells: 0.
  Slide TCGA-20-0996-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 18; Percent necrosis: 2; Percent stromal cells: 0.
- Sample TCGA-20-0996-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Liposomal Doxorubicin.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 5: Pharmaceutical therapy drug name: Taxol.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,196 days; disease-specific survival: no event (censored), 2,196 days; progression-free interval: no event (censored), 2,196 days.
